Somatic mutation profile of tumor specimen TARGET-10-PATMXN-09A (aliquot TARGET-10-PATMXN-09A-01D) from TARGET case TARGET-10-PATMXN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.9 years (5,450 days).
Specimen TARGET-10-PATMXN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d05af65-571e-4923-983f-a1f8a34a6544.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATMXN-10A (Blood Derived Normal), aliquot TARGET-10-PATMXN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6648c48f-c40a-4035-860f-29fed85f1710

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, 5'UTR 2, 5'Flank 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770500550, CM1311775, COSV54106836; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C7orf33 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV61023001; called by muse, varscan2
- ITGAV | c.1888A>G p.N630D | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53711516; called by muse, varscan2
- KNTC1 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61079759; called by muse, mutect2, varscan2
- MUC16 | c.23876G>T p.W7959L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.065); catalogued as COSV67462932; called by muse, mutect2
- PPARGC1A | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99338365; called by muse, mutect2
- RELCH | c.1037C>A p.T346N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56883152; called by muse, varscan2
- RFPL4A | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs752204786, COSV70455155; called by muse, mutect2, varscan2
- RPP40 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs776679398, COSV60291849, COSV99061198; called by mutect2, varscan2
- RYR3 | c.12047C>A p.P4016Q (on ENST00000389232; = p.P4017Q on NM_001036.6) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.111); catalogued as rs1436216952; called by muse, mutect2
- HIVEP2 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- KDM4C | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2
- MGAM2 | c.1093C>A p.Q365K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PPP2R2B | c.1052G>T p.S351I (on ENST00000394409; = p.S417I on NM_181674.2) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- RESF1 | c.3917C>A p.S1306Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- RRM1 | c.577_579del p.L193del | In Frame Del (DEL) | VAF 43/140 reads (31%) | called by pindel, varscan2
- SLC5A7 | c.1473C>A p.N491K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.186); called by muse, mutect2
- TRAPPC8 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF669 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- ZNF837 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- AGAP3 | c.948C>T p.I316= (on ENST00000622464; = p.I352= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs372956092; called by muse, mutect2, varscan2
- MS4A18 | c.246A>T p.R82= | Silent (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- NR2F1 | c.879G>A p.V293= | Silent (SNP) | VAF 17/25 reads (68%) | called by muse, varscan2
- ASH1L | chr1:155563421 C>A | 5'Flank (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- CHCHD6 | c.411+47166C>A | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- NFKBID | c.-273G>T | 5'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- ZNF587B | c.-9C>T | 5'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, varscan2
